Somatic mutation profile of tumor specimen TCGA-64-1678-01A (aliquot TCGA-64-1678-01A-01W-0928-08) from TCGA case TCGA-64-1678, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 71.0 years (25,931 days).
Specimen TCGA-64-1678-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bac6293-bbc5-497f-b167-b9d136a7baa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-64-1678-10A (Blood Derived Normal), aliquot TCGA-64-1678-10A-01D-1489-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c088dc0-a88b-4a2b-b063-56ac05cc2e81

The open-access MAF lists 454 somatic variants for this specimen: 352 protein-altering or splice-affecting, 92 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 299, Silent 92, Nonsense Mutation 31, Frame Shift Del 13, Splice Site 6, RNA 6, Frame Shift Ins 3, Intron 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 158/700 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs869025608, COSV61068581, COSV61070413; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1604T>A p.I535N (on ENST00000404938 / NM_001163941.2; = p.I90N on NM_178559.6) | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51711466, COSV99327563; called by muse, mutect2, varscan2
- ABCC10 | c.839C>T p.A280V (on ENST00000372530 / NM_001198934.2; = p.A237V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as COSV55084735; called by muse, mutect2, varscan2
- ABL2 | c.1734G>T p.K578N (on ENST00000502732 / NM_007314.4; = p.K563N on NM_005158.5) | Missense Mutation (SNP) | VAF 82/290 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV61015291; called by muse, mutect2, varscan2
- ADAM32 | c.882G>T p.M294I | Missense Mutation (SNP) | VAF 103/161 reads (64%) | SIFT tolerated (0.5); PolyPhen benign (0.124); catalogued as COSV65950075; called by muse, mutect2, varscan2
- ADAMTS1 | c.1583G>A p.W528* | Nonsense Mutation (SNP) | VAF 85/154 reads (55%) | catalogued as COSV53170931, COSV53171284; called by muse, mutect2, varscan2
- ADAMTS20 | c.845A>G p.Y282C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67132949; called by muse, mutect2, varscan2
- ADAMTS5 | c.2155G>T p.D719Y | Missense Mutation (SNP) | VAF 92/625 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53179908; called by muse, mutect2, varscan2
- ADAMTS5 | c.1918C>A p.Q640K | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV53179920; called by muse, mutect2
- ADAMTSL3 | c.3215C>A p.S1072Y | Missense Mutation (SNP) | VAF 106/256 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV54451524, COSV99718158; called by muse, mutect2, varscan2
- ADD3 | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 82/168 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV53322852; called by muse, mutect2, varscan2
- ADGRA3 | c.1777G>T p.V593F | Missense Mutation (SNP) | VAF 117/648 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV51563896, COSV51568750; called by muse, mutect2, varscan2
- AFP | c.989T>A p.L330Q | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56925522; called by muse, mutect2, varscan2
- AK2 | c.382G>A p.E128K (on ENST00000354858; = p.E170K on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as rs1335543412, COSV61467932; called by muse, mutect2, varscan2
- AKAP11 | c.5451G>A p.M1817I | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as COSV50297505; called by muse, mutect2
- AKR7A3 | c.728A>T p.E243V | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV64389331; called by muse, mutect2, varscan2
- ANK1 | c.3287C>G p.P1096R | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55883723; called by muse, mutect2, varscan2
- ANK2 | c.670-1G>A p.X224_splice | Splice Site (SNP) | VAF 49/132 reads (37%) | catalogued as COSV52184628; called by muse, mutect2, varscan2
- ANK2 | c.7189T>C p.S2397P | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV52165582; called by muse, mutect2, varscan2
- ANKRD30A | c.927G>T p.L309F (on ENST00000611781; = p.L253F on NM_052997.2) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.587); catalogued as COSV64612241; called by muse, mutect2, varscan2
- ANLN | c.2419T>A p.S807T | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.609); catalogued as COSV56076947; called by muse, mutect2, varscan2
- AP3B2 | c.701G>A p.W234* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as rs775376816, COSV55610250; called by mutect2, varscan2
- APOB | c.13510G>A p.D4504N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.928); catalogued as COSV51938586; called by muse, mutect2, varscan2
- ARFGEF1 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51609904, COSV99142081; called by muse, mutect2, varscan2
- ARHGAP10 | c.1411A>G p.M471V | Missense Mutation (SNP) | VAF 95/432 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV60600573; called by muse, mutect2, varscan2
- ARHGAP12 | c.515A>T p.N172I | Missense Mutation (SNP) | VAF 156/469 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV60963876; called by muse, mutect2, varscan2
- ARHGAP32 | c.6045C>A p.S2015R (on ENST00000310343 / NM_001378025.1; = p.S1666R on NM_014715.4) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.235); catalogued as COSV59849352; called by muse, mutect2, varscan2
- ARHGAP5 | c.2591G>T p.G864V | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV100565631, COSV61536013; called by muse, mutect2, varscan2
- ARID1A | c.5782A>T p.K1928* | Nonsense Mutation (SNP) | VAF 209/408 reads (51%) | catalogued as COSV61379286; called by muse, mutect2, varscan2
- ARMC3 | c.781C>A p.L261I | Missense Mutation (SNP) | VAF 147/434 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV53062422; called by muse, mutect2, varscan2
- ARRDC4 | c.626-1G>T p.X209_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | catalogued as COSV51419436; called by muse, varscan2
- ASXL3 | c.5344C>A p.L1782I | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV52468262; called by muse, mutect2, varscan2
- ATP10B | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs751050963, COSV58778539; called by muse, mutect2, varscan2
- ATP1B3 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 153/232 reads (66%) | SIFT tolerated (0.69); PolyPhen benign (0.029); catalogued as COSV53950136; called by muse, mutect2, varscan2
- ATXN2L | c.1954G>C p.E652Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs373472808, COSV57377441; called by muse, mutect2, varscan2
- BANK1 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 51/153 reads (33%) | catalogued as COSV59844205; called by muse, mutect2, varscan2
- BCAS3 | c.2414C>T p.S805L (on ENST00000390652 / NM_001353144.2; = p.S790L on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV66775346; called by muse, mutect2, varscan2
- BRD4 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.611); catalogued as COSV54587259; called by muse, mutect2, varscan2
- CACNA1E | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV62399431; called by muse, mutect2, varscan2
- CACNA2D1 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV62375168; called by muse, mutect2, varscan2
- CADM3 | c.471C>A p.S157R (on ENST00000368125 / NM_001127173.3; = p.S191R on NM_021189.5) | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63685798; called by muse, mutect2, varscan2
- CAGE1 | c.2171C>A p.S724Y (on ENST00000512086; = p.S588Y on NM_205864.3) | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as COSV57078006; called by muse, mutect2, varscan2
- CARD11 | c.1323C>A p.D441E | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV67799729; called by muse, mutect2, varscan2
- CASS4 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 110/285 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64386759; called by muse, mutect2, varscan2
- CC2D1B | c.2013G>T p.Q671H | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.633); catalogued as COSV52560729, COSV52560995; called by muse, mutect2, varscan2
- CCDC173 | c.806G>T p.R269M | Missense Mutation (SNP) | VAF 333/840 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.452); catalogued as COSV69573172; called by muse, mutect2, varscan2
- CCDC63 | c.1013C>A p.T338K | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.061); catalogued as COSV57528902; called by muse, mutect2, varscan2
- CCKAR | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.017); catalogued as COSV55161925; called by muse, mutect2, varscan2
- CD177 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs200006364; called by muse, mutect2, varscan2
- CDH2 | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 52/237 reads (22%) | catalogued as COSV52276075; called by muse, mutect2, varscan2
- CDH23 | c.5693C>T p.A1898V | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV56469230; called by muse, mutect2, varscan2
- CEP126 | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54826164; called by muse, mutect2, varscan2
- CFAP52 | c.1748G>A p.G583E | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53303442; called by muse, mutect2
- CHAT | c.1891G>C p.A631P | Missense Mutation (SNP) | VAF 112/249 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM119383, COSV60326119, COSV60326509; called by muse, mutect2, varscan2
- CHL1 | c.2808G>T p.W936C (on ENST00000397491 / NM_001253387.1; = p.W952C on NM_006614.4) | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56595387; called by muse, mutect2, varscan2
- CHORDC1 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.358); catalogued as COSV57706208; called by muse, mutect2, varscan2
- CKAP4 | c.1534A>T p.T512S | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV65172700; called by muse, mutect2, varscan2
- CLDN8 | c.185T>A p.M62K | Missense Mutation (SNP) | VAF 52/282 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54526151; called by muse, mutect2, varscan2
- CLN3 | c.338G>A p.G113E (on ENST00000360019 / NM_001286104.2; = p.G137E on NM_000086.2) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV61106082; called by muse, mutect2, varscan2
- CLNK | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as rs1323501586; called by muse, mutect2, varscan2
- CMA1 | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 86/162 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764546466, COSV51625681; called by muse, mutect2, varscan2
- CNGB3 | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV60690403, COSV60691116; called by muse, mutect2, varscan2
- CNTLN | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52064526, COSV52081442; called by muse, mutect2, varscan2
- COL11A1 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 104/183 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62185622; called by muse, mutect2, varscan2
- COL21A1 | c.2848C>T p.P950S | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV55163014; called by muse, mutect2, varscan2
- COPB1 | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 57/341 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV51448792; called by muse, mutect2, varscan2
- COQ4 | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as COSV55957203; called by muse, mutect2, varscan2
- CPXCR1 | c.701G>T p.R234M | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52162102; called by muse, mutect2, varscan2
- CREG2 | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV61316965; called by muse, mutect2, varscan2
- CRYBA4 | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV61322096; called by muse, mutect2, varscan2
- CSMD3 | c.6038C>A p.T2013K (on ENST00000297405 / NM_001363185.1; = p.T1909K on NM_052900.3) | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs765053031, COSV52202200, COSV52340305; called by muse, mutect2, varscan2
- CYLC1 | c.1389G>T p.K463N | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.169); catalogued as COSV61412708; called by muse, mutect2, varscan2
- DACH1 | c.895C>G p.P299A | Missense Mutation (SNP) | VAF 71/129 reads (55%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as rs369421581; called by muse, mutect2, varscan2
- DAGLA | c.1372G>T p.G458C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV57196830; called by muse, mutect2, varscan2
- DDC | c.877-2A>T p.X293_splice | Splice Site (SNP) | VAF 15/58 reads (26%) | catalogued as COSV63565519; called by muse, mutect2, varscan2
- DIP2A | c.3823G>T p.V1275L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.277); catalogued as COSV59479041; called by muse, mutect2, varscan2
- DLEC1 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57300816; called by muse, mutect2, varscan2
- DLGAP1 | c.1263C>A p.D421E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.207); catalogued as COSV59809189; called by muse, mutect2, varscan2
- DNAH10 | c.3031G>T p.E1011* (on ENST00000409039; = p.E950* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 57/162 reads (35%) | catalogued as rs561113993, COSV68995120; called by muse, mutect2, varscan2
- EDIL3 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56901571, COSV56902996; called by muse, mutect2, varscan2
- EIF2D | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV55113916; called by muse, mutect2, varscan2
- EML2 | c.1823G>T p.R608L | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs967203926, COSV55600230; called by muse, mutect2, varscan2
- ENPP2 | c.2106G>T p.M702I (on ENST00000075322 / NM_001040092.3; = p.M754I on NM_006209.5) | Missense Mutation (SNP) | VAF 213/490 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1367586893, COSV50017528; called by muse, mutect2, varscan2
- EPHA5 | c.2357C>A p.A786E | Missense Mutation (SNP) | VAF 105/198 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV56649453; called by muse, mutect2, varscan2
- ERCC6L2 | c.1089G>T p.K363N | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV56631304; called by muse, mutect2, varscan2
- ESYT2 | c.2557G>T p.D853Y (on ENST00000613624; = p.D777Y on NM_020728.3) | Missense Mutation (SNP) | VAF 81/486 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51751957; called by muse, mutect2, varscan2
- ETAA1 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55473364; called by muse, mutect2, varscan2
- F13A1 | c.1193G>T p.S398I | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as CM161504, COSV53560075, COSV99342810; called by muse, mutect2, varscan2
- F5 | c.1943G>A p.G648E | Missense Mutation (SNP) | VAF 71/382 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63124910; called by muse, mutect2, varscan2
- FAM181B | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV100235100; called by muse, mutect2
- FAM214A | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.863); catalogued as COSV55924809; called by muse, mutect2, varscan2
- FAM98C | c.680G>T p.C227F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV53039014; called by muse, mutect2, varscan2
- FBN2 | c.8232C>G p.Y2744* | Nonsense Mutation (SNP) | VAF 68/172 reads (40%) | catalogued as COSV52518830; called by muse, varscan2
- FCRL5 | c.229G>T p.V77F | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV62515435; called by muse, mutect2, varscan2
- FEM1A | c.1460A>T p.D487V | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54164074; called by muse, mutect2, varscan2
- FER1L6 | c.1670C>A p.P557Q | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67550489, COSV67552814; called by muse, mutect2, varscan2
- FIGN | c.152A>T p.Q51L | Missense Mutation (SNP) | VAF 228/652 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV60767620; called by muse, mutect2, varscan2
- FLG2 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV66169308; called by muse, mutect2, varscan2
- FRG2B | c.160A>T p.K54* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as COSV71043111; called by muse, mutect2, varscan2
- FRMPD4 | c.2570C>A p.A857D | Missense Mutation (SNP) | VAF 109/205 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV66216359; called by muse, mutect2, varscan2
- FSHR | c.1896C>A p.N632K | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV58625057; called by muse, mutect2, varscan2
- FTSJ1 | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV50025966; called by muse, mutect2, varscan2
- GLI3 | c.1417G>T p.E473* | Nonsense Mutation (SNP) | VAF 50/120 reads (42%) | catalogued as COSV67889420; called by muse, varscan2
- GNPTAB | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 212/689 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.923); catalogued as rs985184620, COSV54778162; called by muse, mutect2, varscan2
- GPR26 | c.913T>G p.C305G | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV52934337; called by muse, mutect2, varscan2
- GRIA1 | c.632C>G p.A211G | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV53606604; called by muse, mutect2, varscan2
- GRIN2A | c.1202C>A p.P401Q | Missense Mutation (SNP) | VAF 87/276 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.415); catalogued as COSV58032859, COSV58037182; called by muse, mutect2, varscan2
- GRIN3A | c.1245C>A p.S415R | Missense Mutation (SNP) | VAF 79/387 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV62454615; called by muse, mutect2, varscan2
- GRM8 | c.1592G>A p.G531E | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100285091, COSV58800535; called by muse, mutect2, varscan2
- GTF2H1 | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 56/228 reads (25%) | catalogued as COSV56378815; called by muse, mutect2, varscan2
- GUCY1A1 | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV56652349; called by muse, mutect2
- H2AC14 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100297629, COSV60797902; called by muse, varscan2
- HCN1 | c.1889G>T p.R630M | Missense Mutation (SNP) | VAF 96/262 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57515410; called by muse, mutect2, varscan2
- HMCN1 | c.7549G>T p.G2517W | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1424541351, COSV99630866; called by muse, mutect2, varscan2
- HOXD11 | c.985C>A p.L329M | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV50911451, COSV50912697; called by muse, mutect2, varscan2
- ICE1 | c.6361G>T p.D2121Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56826745; called by muse, mutect2, varscan2
- IFI16 | c.2041C>A p.Q681K (on ENST00000295809 / NM_001364867.2; = p.Q625K on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as COSV55535027; called by muse, mutect2, varscan2
- IGHV4-39 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 152/428 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs587716511; called by muse, mutect2, varscan2
- IGLV6-57 | c.350A>C p.N117T | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as rs551590153, COSV66504141; called by muse, mutect2, varscan2
- IL2RB | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.074); catalogued as COSV53426757; called by muse, mutect2, varscan2
- IL7R | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.073); catalogued as COSV57409233; called by muse, mutect2, varscan2
- INPP4B | c.968-1G>T p.X323_splice | Splice Site (SNP) | VAF 12/43 reads (28%) | catalogued as COSV53728757; called by muse, mutect2, varscan2
- INSRR | c.3088G>T p.E1030* | Nonsense Mutation (SNP) | VAF 51/117 reads (44%) | catalogued as COSV63871805, COSV63874314; called by muse, mutect2, varscan2
- ITGBL1 | c.1454G>T p.C485F | Missense Mutation (SNP) | VAF 239/422 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65945444; called by muse, mutect2, varscan2
- ITK | c.305G>T p.W102L | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70062825; called by muse, mutect2, varscan2
- ITSN1 | c.590A>C p.K197T | Missense Mutation (SNP) | VAF 142/240 reads (59%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.954); catalogued as COSV66083724; called by muse, mutect2, varscan2
- KCNK2 | c.700T>G p.C234G (on ENST00000444842 / NM_001017425.3; = p.C219G on NM_014217.4) | Missense Mutation (SNP) | VAF 112/287 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV67206690; called by muse, mutect2, varscan2
- KCNK9 | c.591G>T p.L197F | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57282524; called by muse, mutect2, varscan2
- KCTD3 | c.1768G>T p.E590* | Nonsense Mutation (SNP) | VAF 60/241 reads (25%) | catalogued as COSV52067376; called by muse, mutect2, varscan2
- KMT2C | c.3413C>A p.P1138H | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV51448845; called by muse, mutect2, varscan2
- KMT2D | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 189/472 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV56449399; called by muse, mutect2, varscan2
- KRTAP10-9 | c.491A>T p.Q164L | Missense Mutation (SNP) | VAF 81/403 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV59965840; called by muse, mutect2, varscan2
- KRTAP4-4 | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66811349; called by muse, mutect2, varscan2
- KTN1 | c.2873G>C p.S958T | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.108); catalogued as COSV63215624; called by muse, mutect2, varscan2
- LDB3 | c.1882A>T p.T628S | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53942919; called by muse, mutect2, varscan2
- LRBA | c.7987G>T p.D2663Y | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63956801; called by muse, mutect2, varscan2
- LRFN2 | c.1426T>G p.F476V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57828422; called by muse, mutect2, varscan2
- LRRC37A3 | c.3625C>A p.P1209T | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58534301, COSV58535602; called by muse, mutect2, varscan2
- LRRC40 | c.407G>T p.S136I | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63942476; called by muse, mutect2, varscan2
- LRRIQ1 | c.4385C>T p.T1462I | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV67832023; called by muse, mutect2, varscan2
- LRRN2 | c.1292dup p.S432Kfs*75 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | catalogued as rs1186903618; called by pindel, varscan2
- LRRTM3 | c.1574A>T p.Y525F | Missense Mutation (SNP) | VAF 68/360 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.404); catalogued as COSV63666608; called by muse, mutect2, varscan2
- LYST | c.7832G>A p.R2611H | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs147536126; called by muse, mutect2, varscan2
- MAGEB6B | c.418C>A p.R140S | Missense Mutation (SNP) | VAF 96/165 reads (58%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV69689600; called by muse, mutect2, varscan2
- MAGI2 | c.856C>A p.Q286K | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs749690483, COSV62667048; called by muse, mutect2, varscan2
- MAML2 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs771918587, COSV73263723; called by muse, mutect2, varscan2
- MCOLN2 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 78/124 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.19); catalogued as COSV52296401; called by muse, mutect2, varscan2
- MEOX2 | c.714G>T p.R238S | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56290777; called by muse, mutect2, varscan2
- METTL18 | c.810G>T p.W270C | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53679558; called by muse, mutect2, varscan2
- MFSD8 | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM1411782; called by muse, mutect2, varscan2
- MLKL | c.1300G>T p.G434C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58205444; called by muse, mutect2, varscan2
- MMP1 | c.640C>A p.R214S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV59510319, COSV59510620; called by muse, mutect2, varscan2
- MSRB3 | c.511A>T p.S171C | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV57592245; called by muse, mutect2, varscan2
- MTHFSD | c.256G>T p.V86F (on ENST00000360900 / NM_001159377.2; = p.V85F on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59803645; called by muse, mutect2, varscan2
- MUC16 | c.12835C>A p.H4279N | Missense Mutation (SNP) | VAF 264/364 reads (73%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); catalogued as COSV67471757; called by muse, mutect2, varscan2
- MUC4 | c.2228C>G p.S743C | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); catalogued as rs1417450264, COSV62155221; called by muse, mutect2, varscan2
- MXRA5 | c.6452C>A p.T2151N | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV54238034; called by muse, mutect2, varscan2
- MYBPC2 | c.1997G>A p.G666E | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777749471, COSV63096388; called by muse, mutect2, varscan2
- MYO9A | c.2719C>T p.Q907* | Nonsense Mutation (SNP) | VAF 44/961 reads (5%) | catalogued as COSV61852212; called by muse, mutect2
- MYPN | c.1307T>C p.V436A | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV62734723; called by muse, mutect2, varscan2
- N6AMT1 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58134692; called by muse, mutect2, varscan2
- NBN | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV55373659; called by muse, mutect2, varscan2
- NCOA7 | c.1771G>T p.V591L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1483088840, COSV57656133; called by muse, mutect2, varscan2
- NHS | c.3896T>A p.V1299E | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.189); catalogued as COSV66276438; called by muse, mutect2, varscan2
- NLRP4 | c.2869C>A p.L957M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56715398; called by muse, mutect2, varscan2
- NODAL | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99755413; called by muse, mutect2, varscan2
- NOX5 | c.1611G>C p.R537S | Missense Mutation (SNP) | VAF 35/424 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV52989813; called by muse, mutect2
- NR6A1 | c.670C>T p.Q224* (on ENST00000487099 / NM_033334.4; = p.Q219* on NM_001489.5) | Nonsense Mutation (SNP) | VAF 97/195 reads (50%) | catalogued as rs1469722487, COSV60634024; called by muse, mutect2, varscan2
- NUP188 | c.894G>T p.Q298H | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as rs1344812045, COSV65362495; called by muse, mutect2, varscan2
- OR10W1 | c.337C>A p.R113S | Missense Mutation (SNP) | VAF 97/219 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV67720315, COSV67720527, COSV67720543; called by muse, mutect2, varscan2
- OR1A1 | c.221C>A p.S74* | Nonsense Mutation (SNP) | VAF 376/894 reads (42%) | catalogued as COSV100410830, COSV58403914; called by muse, mutect2, varscan2
- OR4C13 | c.919A>T p.S307C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as COSV73648783; called by muse, mutect2, varscan2
- OR4D2 | c.333G>C p.M111I | Missense Mutation (SNP) | VAF 111/174 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV73459782; called by muse, mutect2, varscan2
- OR4F6 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 165/966 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV61026960, COSV61027837; called by muse, mutect2, varscan2
- OR52A5 | c.209C>A p.A70D | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV56615504, COSV56617184; called by muse, mutect2, varscan2
- OR52E4 | c.5C>A p.P2H | Missense Mutation (SNP) | VAF 72/316 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV57625066; called by muse, mutect2, varscan2
- OR5AP2 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV57257811; called by muse, mutect2, varscan2
- OR5W2 | c.772A>T p.M258L | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as COSV60616474; called by muse, mutect2, varscan2
- OR6N1 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100625080, COSV58648903; called by muse, mutect2, varscan2
- OTOP3 | c.470G>T p.C157F | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as COSV60913650; called by muse, mutect2, varscan2
- OVCH1 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58964124; called by muse, mutect2, varscan2
- PAX1 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV68272160; called by muse, mutect2, varscan2
- PCDH1 | c.1373T>G p.L458R | Missense Mutation (SNP) | VAF 90/457 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54614745; called by muse, mutect2, varscan2
- PCDHA10 | c.1451A>T p.Q484L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.114); catalogued as COSV56509827; called by muse, mutect2, varscan2
- PCDHA4 | c.1948C>A p.L650M | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); catalogued as COSV63542492; called by muse, mutect2, varscan2
- PCDHB4 | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 85/355 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV52022084, COSV52023347; called by muse, mutect2, varscan2
- PCDHB6 | c.1700C>A p.S567Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV50700851; called by muse, mutect2, varscan2
- PCLO | c.5066C>A p.T1689K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.058); catalogued as COSV61639820; called by muse, mutect2, varscan2
- PDCD11 | c.4012G>T p.G1338C | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63934198; called by muse, mutect2, varscan2
- PDE10A | c.1651C>T p.L551F | Missense Mutation (SNP) | VAF 139/534 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); catalogued as COSV63098133; called by muse, mutect2, varscan2
- PGM2 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 13/289 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.492); catalogued as COSV67938317; called by muse, mutect2
- PHACTR4 | c.1745G>A p.G582E (on ENST00000373839 / NM_001350159.2; = p.G592E on NM_023923.4) | Missense Mutation (SNP) | VAF 84/416 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV65784192; called by muse, mutect2, varscan2
- PI15 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 209/570 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs759660126, COSV52642013; called by muse, mutect2, varscan2
- PIEZO2 | c.8161G>T p.G2721* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | catalogued as COSV53290377; called by muse, mutect2, varscan2
- PIK3C2B | c.4828C>T p.R1610C | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs747003072, COSV65812037; called by muse, mutect2, varscan2
- PIK3CG | c.1781G>A p.S594N | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.309); catalogued as rs1212528123, COSV63249218; called by muse, mutect2, varscan2
- PIP5K1A | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.058); catalogued as COSV62958485, COSV62960486; called by muse, mutect2, varscan2
- PLCG2 | c.2375G>T p.R792L | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV63869931; called by muse, mutect2, varscan2
- PLCXD2 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 49/177 reads (28%) | catalogued as COSV67340419; called by muse, mutect2, varscan2
- PLEKHH1 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as COSV100233559, COSV61284134; called by muse, mutect2, varscan2
- POT1 | c.828G>T p.R276S | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.107); catalogued as rs76496261; called by muse, mutect2, varscan2
- POTEF | c.2337G>T p.W779C | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV62541553; called by muse, mutect2, varscan2
- POU6F2 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.461); catalogued as COSV101302603, COSV68874592; called by muse, mutect2, varscan2
- PPP1R3A | c.3106C>T p.Q1036* | Nonsense Mutation (SNP) | VAF 262/634 reads (41%) | catalogued as COSV52884317, COSV52886792; called by muse, mutect2, varscan2
- PPP1R9A | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs140508899; called by muse, varscan2
- PRKDC | c.965A>T p.Q322L | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV58054567; called by muse, mutect2, varscan2
- PTH2R | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757913275, COSV55916751; called by muse, mutect2, varscan2
- PXDN | c.3284A>T p.H1095L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV53236540; called by muse, mutect2, varscan2
- PXDNL | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 242/406 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV62489344; called by muse, mutect2, varscan2
- RABGAP1 | c.579A>T p.E193D | Missense Mutation (SNP) | VAF 223/471 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as COSV58060340; called by muse, mutect2, varscan2
- RASGRF2 | c.850A>G p.I284V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as COSV54131363; called by muse, varscan2
- RPGRIP1L | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100045694, COSV100045883, COSV50908103; called by muse, mutect2, varscan2
- RSPH14 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 40/89 reads (45%) | catalogued as COSV53269169; called by muse, mutect2, varscan2
- RYR1 | c.6212G>T p.R2071L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.392); catalogued as COSV62099638; called by muse, mutect2, varscan2
- SACS | c.8233G>T p.E2745* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as COSV66541095, COSV66547236; called by muse, mutect2, varscan2
- SAMD9 | c.1373G>T p.S458I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV66075954; called by muse, mutect2, varscan2
- SBSPON | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 32/456 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.93); catalogued as COSV52075698, COSV52076802; called by muse, mutect2
- SEC16B | c.2863G>T p.G955C | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV57626550; called by muse, mutect2, varscan2
- SEC24B | c.3034G>T p.G1012* | Nonsense Mutation (SNP) | VAF 74/159 reads (47%) | catalogued as COSV54500843; called by muse, mutect2, varscan2
- SELPLG | c.265C>G p.R89G | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1018628959, COSV57312136; called by muse, mutect2, varscan2
- SEMA5A | c.1235G>C p.G412A | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.045); catalogued as COSV66790399, COSV66795323; called by muse, mutect2, varscan2
- SERPINB11 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 108/197 reads (55%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as COSV66957093; called by muse, mutect2, varscan2
- SERPINB7 | c.156_157del p.Q53Dfs*2 | Frame Shift Del (DEL) | VAF 82/372 reads (22%) | catalogued as rs776228261; called by pindel, varscan2
- SHPK | c.1201G>T p.A401S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); catalogued as COSV56649300; called by muse, mutect2, varscan2
- SIGLECL1 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 104/399 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.279); catalogued as COSV57063204; called by muse, mutect2, varscan2
- SIK3 | c.3268C>T p.Q1090* (on ENST00000445177 / NM_001366686.2; = p.Q1048* on NM_025164.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV52615912; called by muse, mutect2, varscan2
- SLC12A1 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV57710023; called by muse, mutect2, varscan2
- SLC16A12 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 22/247 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100369994, COSV57950826; called by muse, mutect2
- SLC24A4 | c.1798T>A p.C600S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as rs369241030; called by muse, mutect2, varscan2
- SLC26A8 | c.2459C>A p.S820* | Nonsense Mutation (SNP) | VAF 117/240 reads (49%) | catalogued as COSV62885157; called by muse, mutect2, varscan2
- SLC5A4 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.063); catalogued as COSV56671073, COSV56671808; called by muse, mutect2, varscan2
- SLC5A8 | c.1186T>A p.C396S | Missense Mutation (SNP) | VAF 219/630 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV73310743; called by muse, mutect2, varscan2
- SLC8A1 | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 100/337 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60479171, COSV60497582; called by muse, mutect2, varscan2
- SNTG2 | c.573C>A p.N191K | Missense Mutation (SNP) | VAF 208/636 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57983606; called by muse, mutect2, varscan2
- SOX5 | c.1927G>A p.G643S | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as COSV58632778; called by muse, mutect2, varscan2
- SPATA31E1 | c.2205G>T p.E735D | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV57792435; called by muse, mutect2, varscan2
- SPATA6 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV64057349; called by muse, mutect2, varscan2
- SPHKAP | c.1030G>C p.A344P | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.844); catalogued as COSV60882165, COSV60895655; called by muse, mutect2, varscan2
- STON2 | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 72/286 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50846017; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 108/180 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.435); catalogued as rs1316617227; called by muse, mutect2, varscan2
- TAF9B | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 28/818 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV59371463; called by muse, mutect2
- TAS2R9 | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 169/421 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV53689057; called by muse, mutect2, varscan2
- TCEAL6 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 254/473 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV65653997; called by muse, mutect2, varscan2
- TCF4 | c.1733G>T p.R578L | Missense Mutation (SNP) | VAF 151/369 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM105053, COSV61898366; called by muse, mutect2, varscan2
- TCP11L1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV57515648; called by muse, mutect2, varscan2
- TCTE1 | c.617T>A p.L206H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV65255699; called by muse, mutect2
- TDP2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 46/397 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs143844222, COSV57764631; called by muse, mutect2, varscan2
- TENM2 | c.4967T>A p.I1656N (on ENST00000518659 / NM_001122679.2; = p.I1417N on NM_001080428.3) | Missense Mutation (SNP) | VAF 208/872 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV69132303; called by muse, mutect2, varscan2
- TENM4 | c.5005G>T p.E1669* | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as COSV53635346; called by muse, mutect2, varscan2
- TEX10 | c.1963G>T p.G655W | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV66515755; called by muse, mutect2, varscan2
- TEX11 | c.767A>T p.K256M (on ENST00000344304; = p.K241M on NM_031276.3) | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.944); catalogued as COSV60232121; called by muse, mutect2, varscan2
- THUMPD2 | c.307G>T p.G103* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV53187858; called by muse, mutect2, varscan2
- TLE4 | c.1861G>T p.G621* | Nonsense Mutation (SNP) | VAF 66/138 reads (48%) | catalogued as COSV54633283; called by muse, mutect2, varscan2
- TMEM132D | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV70607779; called by muse, mutect2, varscan2
- TMLHE | c.64A>T p.I22L | Missense Mutation (SNP) | VAF 168/834 reads (20%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV57687741; called by muse, mutect2, varscan2
- TMPRSS15 | c.1990G>T p.G664C | Missense Mutation (SNP) | VAF 179/500 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53041233; called by muse, mutect2, varscan2
- TNN | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as COSV53427934; called by muse, mutect2, varscan2
- TNRC6C | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV56946436; called by muse, mutect2, varscan2
- TOGARAM1 | c.3932G>T p.R1311L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63892585, COSV63895316; called by muse, mutect2, varscan2
- TP53 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; called by muse, mutect2, varscan2
- TRAPPC12 | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 78/217 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.621); catalogued as COSV60848185; called by muse, mutect2, varscan2
- TREML2 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.641); catalogued as rs768840352, COSV72439154; called by muse, mutect2, varscan2
- TRHDE | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53847758; called by muse, mutect2, varscan2
- TRPC6 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); catalogued as rs199747455, COSV60250522; called by muse, mutect2, varscan2
- TSPAN7 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV54531438; called by muse, mutect2, varscan2
- UGT2B28 | c.890A>T p.Q297L | Missense Mutation (SNP) | VAF 92/367 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV59432574; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3623G>T p.G1208V | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54438324; called by muse, mutect2, varscan2
- VAV3 | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 67/93 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV58384039; called by muse, mutect2, varscan2
- VIRMA | c.3536G>T p.R1179L | Missense Mutation (SNP) | VAF 91/251 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52586043; called by muse, mutect2, varscan2
- VNN3 | c.615del p.K206Sfs*25 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as COSV99258315; called by mutect2, pindel, varscan2
- VRK2 | c.653G>T p.S218I | Missense Mutation (SNP) | VAF 80/229 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60877492; called by muse, mutect2, varscan2
- WDR93 | c.215G>T p.W72L | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.586); catalogued as rs200074926, COSV51532875; called by muse, mutect2, varscan2
- XDH | c.3217C>G p.P1073A | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV101052313, COSV65149246; called by muse, mutect2, varscan2
- XIRP1 | c.1702C>A p.Q568K | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV61138965; called by muse, mutect2, varscan2
- XIRP2 | c.2797G>T p.E933* (on ENST00000628543; = p.E1108* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as COSV54706281; called by muse, mutect2, varscan2
- XPOT | c.1595G>T p.G532V | Missense Mutation (SNP) | VAF 83/305 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60345880; called by muse, mutect2, varscan2
- XYLT1 | c.2047C>A p.P683T | Missense Mutation (SNP) | VAF 95/204 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV54486267; called by muse, varscan2
- ZADH2 | c.91C>A p.Q31K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV59010913; called by muse, mutect2, varscan2
- ZBTB46 | c.1222+1G>T p.X408_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | catalogued as COSV55510121; called by mutect2, varscan2
- ZFHX4 | c.8260A>G p.T2754A | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV50966307; called by muse, mutect2, varscan2
- ZG16B | c.424T>A p.Y142N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as COSV66525920; called by muse, mutect2, varscan2
- ZNF208 | c.2179G>C p.G727R | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV68107397; called by muse, varscan2
- ZNF208 | c.683C>A p.P228H | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV68107412; called by muse, mutect2, varscan2
- ZNF254 | c.887G>T p.C296F | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61642949; called by muse, mutect2, varscan2
- ZNF398 | c.1214G>T p.R405M (on ENST00000475153 / NM_170686.3; = p.R234M on NM_020781.4) | Missense Mutation (SNP) | VAF 81/159 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV60065523; called by muse, mutect2, varscan2
- ZNF510 | c.1991T>C p.L664S | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV56297675; called by muse, mutect2, varscan2
- ZNF519 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV73913406; called by muse, mutect2, varscan2
- ZNF526 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV56630010; called by muse, mutect2, varscan2
- ZNF560 | c.965G>T p.W322L | Missense Mutation (SNP) | VAF 93/131 reads (71%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.468); catalogued as COSV56868427; called by muse, mutect2, varscan2
- ZNF585B | c.1942A>T p.N648Y | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as COSV57215899; called by muse, varscan2
- ZNF610 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 94/265 reads (35%) | catalogued as COSV58345102; called by muse, mutect2, varscan2
- ZXDB | c.2197G>T p.D733Y | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV66492902; called by muse, mutect2, varscan2
- ABCB5 | c.811_812del p.Q271Efs*44 | Frame Shift Del (DEL) | VAF 28/126 reads (22%) | called by pindel, varscan2
- AEN | c.324C>G p.S108R | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by mutect2, varscan2
- AFAP1L2 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, mutect2
- ANK2 | c.670-2A>T p.X224_splice | Splice Site (SNP) | VAF 50/132 reads (38%) | called by muse, mutect2, varscan2
- ATG16L1 | c.392T>C p.I131T | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- CDC14B | c.1030G>C p.V344L | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH8 | c.2294C>A p.T765N | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CPXCR1 | c.702G>T p.R234S | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- DCTN1 | c.1538A>T p.Y513F | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- EPHA5 | c.1372G>T p.V458L | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.346); called by muse, mutect2
- FRG2C | c.656G>C p.C219S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.943); called by muse, mutect2
- GLRX2 | c.224C>A p.T75K (on ENST00000367439 / NM_197962.3; = p.T76K on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- GRIK1 | c.1707del p.F570Sfs*15 | Frame Shift Del (DEL) | VAF 34/107 reads (32%) | called by mutect2, pindel, varscan2
- GRIN2A | c.305del p.D102Afs*8 | Frame Shift Del (DEL) | VAF 26/128 reads (20%) | called by mutect2, varscan2
- GRIN2A | c.304del p.D102Tfs*8 | Frame Shift Del (DEL) | VAF 23/169 reads (14%) | called by mutect2*, pindel, varscan2*
- H3-5 | c.8_9insT p.T4Nfs*7 | Frame Shift Ins (INS) | VAF 18/46 reads (39%) | called by mutect2, pindel*, varscan2
- HAUS6 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HTRA2 | c.1241T>A p.L414* | Nonsense Mutation (SNP) | VAF 123/323 reads (38%) | called by muse, mutect2, varscan2
- HYDIN | c.2629C>A p.L877M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.054); called by mutect2, varscan2
- IGKV1-27 | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IGKV1-5 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IGKV1-6 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ITGBL1 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 15/440 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- KLF4 | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LDHB | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.052); called by mutect2, varscan2
- LRP8 | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LSM14A | c.1078A>T p.N360Y | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- MAGEB2 | c.927A>T p.E309D | Missense Mutation (SNP) | VAF 44/58 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- MAPKBP1 | c.178del p.R60Dfs*4 | Frame Shift Del (DEL) | VAF 74/279 reads (27%) | called by mutect2, pindel, varscan2
- MFSD8 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MRC1 | c.2656G>T p.A886S | Missense Mutation (SNP) | VAF 303/899 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MSANTD3 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NEDD4L | c.1763G>T p.G588V (on ENST00000400345 / NM_001144967.3; = p.G568V on NM_015277.6) | Missense Mutation (SNP) | VAF 80/309 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NFU1 | c.116_117del p.Q39Lfs*43 (on ENST00000410022 / NM_001002755.4; = p.Q15Lfs*43 on NM_015700.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/93 reads (20%) | called by mutect2, pindel, varscan2
- NKX6-1 | c.1046G>C p.S349T | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NOL8 | c.2578G>T p.G860C | Missense Mutation (SNP) | VAF 146/703 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPY2R | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR4A3 | c.342G>T p.Q114H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.276); called by muse, varscan2
- NWD1 | c.4469C>A p.P1490H | Missense Mutation (SNP) | VAF 138/162 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); called by muse, varscan2
- OR4E2 | c.472G>T p.G158W | Missense Mutation (SNP) | VAF 255/519 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- OR5V1 | c.566del p.C189Lfs*33 | Frame Shift Del (DEL) | VAF 114/596 reads (19%) | called by mutect2, pindel, varscan2
- PAM | c.2024G>T p.G675V | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PER2 | c.3593G>T p.G1198V | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PER2 | c.3592G>T p.G1198C | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PEX1 | c.990_1000del p.T331Afs*3 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- PPP1R3C | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRRC2B | c.2336_2337del p.S779Ffs*19 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | called by pindel, varscan2
- RASGRF2 | c.849dup p.I284Hfs*12 | Frame Shift Ins (INS) | VAF 8/60 reads (13%) | called by pindel, varscan2
- SATB2 | c.1598C>A p.T533N | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SECTM1 | c.734C>G p.A245G | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SLC25A22 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPANXB1 | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 216/1232 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); called by muse, varscan2
- SRRM2 | c.5441G>T p.R1814L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SRRM4 | c.378T>A p.Y126* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- TMEM222 | c.302A>T p.K101M | Missense Mutation (SNP) | VAF 101/188 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TMTC3 | c.528del p.T177Qfs*4 | Frame Shift Del (DEL) | VAF 100/311 reads (32%) | called by mutect2, pindel, varscan2
- TP53 | c.428_467del p.V143Afs*14 | Frame Shift Del (DEL) | VAF 28/141 reads (20%) | called by mutect2, pindel
- ZBED1 | c.1728G>T p.K576N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF157 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 137/230 reads (60%) | called by muse, mutect2, varscan2
- ZNF35 | c.857C>A p.A286D | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ACTN2 | c.354C>T p.G118= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs539250948, COSV63975008; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAMTS12 | c.3270C>A p.P1090= | Silent (SNP) | VAF 144/414 reads (35%) | catalogued as COSV61264987; called by muse, mutect2, varscan2
- ADCY4 | c.234C>T p.L78= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs922153554; called by mutect2, varscan2
- ADCY8 | c.3231C>A p.I1077= | Silent (SNP) | VAF 114/328 reads (35%) | catalogued as COSV53903935, COSV53914119; called by muse, mutect2
- ATP12A | c.654C>T p.I218= | Silent (SNP) | VAF 28/197 reads (14%) | catalogued as COSV54517705; called by muse, mutect2, varscan2
- ATP1A2 | c.1692G>T p.R564= | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as COSV63402439, COSV63404133; called by muse, mutect2, varscan2
- B3GALT5 | c.717T>C p.I239= | Silent (SNP) | VAF 62/688 reads (9%) | catalogued as COSV58198850; called by mutect2, varscan2
- BMP4 | c.528C>T p.H176= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV55416214; called by muse, varscan2
- CACNA2D4 | c.2418A>T p.S806= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV54951579; called by muse, mutect2, varscan2
- CLEC16A | c.2583G>T p.R861= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV55490118; called by muse, mutect2, varscan2
- CLPTM1 | c.1734C>T p.F578= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV61612159; called by muse, mutect2, varscan2
- CPXM1 | c.1911G>A p.G637= | Silent (SNP) | VAF 12/180 reads (7%) | catalogued as COSV66045630; called by muse, mutect2
- CSF2RB | c.1194C>A p.A398= | Silent (SNP) | VAF 24/31 reads (77%) | catalogued as COSV53258411, COSV53259903; called by muse, mutect2, varscan2
- CTNND2 | c.2547C>A p.P849= | Silent (SNP) | VAF 59/118 reads (50%) | catalogued as rs774482007, COSV58889928, COSV58894490; called by muse, mutect2, varscan2
- CUL9 | c.2955C>T p.L985= | Silent (SNP) | VAF 37/154 reads (24%) | called by muse, mutect2, varscan2
- DCDC2B | c.711G>A p.Q237= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV52209069; called by muse, mutect2, varscan2
- DDI1 | c.655C>A p.R219= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV56380617, COSV56384400; called by muse, mutect2, varscan2
- DMXL2 | c.1356G>T p.L452= | Silent (SNP) | VAF 64/190 reads (34%) | catalogued as COSV51848040; called by muse, mutect2, varscan2
- EBF3 | c.681C>A p.A227= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV62475914; called by muse, mutect2, varscan2
- EPHA3 | c.1677C>A p.V559= | Silent (SNP) | VAF 74/160 reads (46%) | catalogued as COSV60709513; called by muse, mutect2, varscan2
- FAM171B | c.1050C>A p.A350= | Silent (SNP) | VAF 49/136 reads (36%) | called by muse, mutect2, varscan2
- FAM47A | c.1788T>A p.S596= | Silent (SNP) | VAF 8/107 reads (7%) | catalogued as COSV60497409; called by muse, mutect2
- FAP | c.216A>T p.A72= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as rs751184213, COSV51862654; called by muse, mutect2, varscan2
- FRMPD2 | c.2319T>A p.I773= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as rs781676807, COSV59718862; called by muse, mutect2, varscan2
- GABRR2 | c.69C>T p.P23= | Silent (SNP) | VAF 22/604 reads (4%) | called by muse, mutect2
- GDF2 | c.1074C>A p.G358= | Silent (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- GNPAT | c.1098C>T p.V366= | Silent (SNP) | VAF 23/258 reads (9%) | catalogued as COSV64153590; called by muse, mutect2
- GRM5 | c.267C>A p.I89= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs1034723174, COSV59608616, COSV59628291; called by muse, mutect2, varscan2
- HECTD4 | c.1200C>T p.L400= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV66393302; called by muse, mutect2, varscan2
- HS3ST1 | c.141A>T p.P47= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- IFIH1 | c.2070G>T p.L690= | Silent (SNP) | VAF 33/123 reads (27%) | called by muse, mutect2, varscan2
- IGHV1-58 | c.117C>A p.V39= | Silent (SNP) | VAF 81/148 reads (55%) | called by muse, mutect2, varscan2
- IPO8 | c.129A>T p.I43= | Silent (SNP) | VAF 92/183 reads (50%) | catalogued as COSV56242324; called by muse, mutect2, varscan2
- ITIH5 | c.792C>A p.V264= | Silent (SNP) | VAF 171/587 reads (29%) | called by muse, mutect2, varscan2
- KEL | c.1986G>T p.L662= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs140592001, COSV62335591; called by muse, mutect2, varscan2
- KIF17 | c.1254C>A p.A418= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as COSV99929974; called by muse, mutect2, varscan2
- KIR2DL4 | c.135G>T p.T45= (on ENST00000396284; = p.T6= on NM_001080770.2) | Silent (SNP) | VAF 314/938 reads (33%) | called by muse, mutect2, varscan2
- LCE2C | c.253C>A p.R85= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV64228433; called by muse, mutect2, varscan2
- LRFN2 | c.1203C>A p.G401= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV57828428; called by muse, mutect2, varscan2
- LRRK1 | c.4524G>A p.E1508= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV52614382; called by muse, mutect2, varscan2
- MRGPRX1 | c.207C>A p.A69= | Silent (SNP) | VAF 88/478 reads (18%) | catalogued as rs777988527, COSV57105980; called by muse, mutect2, varscan2
- MS4A10 | c.294G>T p.G98= | Silent (SNP) | VAF 44/140 reads (31%) | catalogued as COSV57632839, COSV57633472; called by muse, mutect2, varscan2
- MUC5AC | c.13854C>T p.T4618= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs1255559885; called by muse, mutect2, varscan2
- MXD4 | c.273G>T p.T91= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV61465960; called by muse, mutect2, varscan2
- NLRP12 | c.435G>T p.A145= | Silent (SNP) | VAF 41/127 reads (32%) | catalogued as COSV100145930, COSV60743750; called by muse, mutect2, varscan2
- NLRP3 | c.2340C>A p.L780= | Silent (SNP) | VAF 95/361 reads (26%) | catalogued as COSV60225546; called by muse, mutect2, varscan2
- NPY2R | c.99C>A p.V33= | Silent (SNP) | VAF 32/119 reads (27%) | called by muse, mutect2, varscan2
- NR1H2 | c.1305G>A p.S435= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs372744682, COSV99516426; called by muse, mutect2, varscan2
- OR11H1 | c.783C>A p.V261= | Silent (SNP) | VAF 53/178 reads (30%) | called by mutect2, varscan2
- OR2F2 | c.912A>G p.L304= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV68832807, COSV68832941; called by muse, mutect2, varscan2
- OR2G2 | c.546C>T p.C182= | Silent (SNP) | VAF 125/475 reads (26%) | catalogued as rs146695930; called by muse, mutect2, varscan2
- OR2M4 | c.324T>C p.L108= | Silent (SNP) | VAF 63/166 reads (38%) | catalogued as COSV60708463; called by muse, mutect2, varscan2
- OR4C13 | c.420C>T p.S140= | Silent (SNP) | VAF 160/345 reads (46%) | catalogued as COSV73648782, COSV73648965; called by muse, mutect2, varscan2
- OR4C15 | c.810C>G p.S270= (on ENST00000314644; = p.S216= on NM_001001920.2) | Silent (SNP) | VAF 317/779 reads (41%) | catalogued as COSV58953246; called by muse, mutect2, varscan2
- OR56A4 | c.885G>T p.T295= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as rs199866327, COSV58110424; called by muse, mutect2, varscan2
- OR8J1 | c.936C>T p.S312= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as rs148720229; called by muse, mutect2, varscan2
- OTOP1 | c.378G>T p.T126= | Silent (SNP) | VAF 3/9 reads (33%) | called by mutect2, varscan2
- PANX1 | c.129G>T p.V43= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV57134073; called by muse, mutect2, varscan2
- PCDH15 | c.2971C>A p.R991= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as CM064158, COSV57264996, COSV57325606; called by muse, mutect2, varscan2
- PCDHB16 | c.1029T>C p.N343= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV53363619; called by mutect2, varscan2
- PCDHGA4 | c.1833C>T p.R611= | Silent (SNP) | VAF 49/200 reads (25%) | catalogued as COSV53963321; called by muse, mutect2, varscan2
- PHLPP1 | c.4719G>T p.R1573= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as COSV53030377; called by muse, mutect2, varscan2
- PIWIL1 | c.1263G>T p.V421= | Silent (SNP) | VAF 201/584 reads (34%) | catalogued as COSV55347629; called by muse, mutect2, varscan2
- PLA2R1 | c.396G>T p.V132= | Silent (SNP) | VAF 140/348 reads (40%) | catalogued as COSV51780182; called by muse, mutect2, varscan2
- POLR3E | c.498G>T p.A166= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV55401189; called by muse, mutect2, varscan2
- PPP2R5B | c.954G>T p.R318= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs777692104, COSV51210546; called by muse, mutect2, varscan2
- PROC | c.1254C>T p.G418= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs775467256, COSV52166292; called by mutect2, varscan2
- PROX1 | c.504G>C p.R168= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV54779727; called by muse, mutect2, varscan2
- ROBO4 | c.3009T>A p.P1003= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV60624800; called by muse, mutect2, varscan2
- RYR2 | c.2268T>C p.S756= | Silent (SNP) | VAF 234/943 reads (25%) | catalogued as COSV63689763; called by muse, mutect2, varscan2
- SARAF | c.294G>A p.K98= | Silent (SNP) | VAF 14/228 reads (6%) | catalogued as COSV56357534; called by muse, mutect2
- SCNN1A | c.1314G>T p.R438= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as COSV57436052; called by muse, mutect2, varscan2
- SH3RF2 | c.903C>A p.I301= | Silent (SNP) | VAF 136/699 reads (19%) | catalogued as COSV63039359, COSV63040140; called by muse, mutect2, varscan2
- SPARCL1 | c.129C>A p.P43= | Silent (SNP) | VAF 116/269 reads (43%) | catalogued as COSV56804173; called by muse, mutect2
- SPDL1 | c.936A>G p.E312= | Silent (SNP) | VAF 35/159 reads (22%) | catalogued as COSV54668437; called by muse, mutect2, varscan2
- TENM1 | c.6396C>A p.R2132= | Silent (SNP) | VAF 221/375 reads (59%) | catalogued as COSV64433802; called by muse, mutect2, varscan2
- TLE4 | c.348G>T p.R116= | Silent (SNP) | VAF 308/645 reads (48%) | catalogued as COSV54630228, COSV54633264; called by muse, mutect2, varscan2
- TMEM214 | c.1641G>T p.L547= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV53192909; called by muse, mutect2, varscan2
- TNRC6C | c.2601G>A p.L867= | Silent (SNP) | VAF 5/8 reads (63%) | catalogued as COSV56946456; called by muse, mutect2, varscan2
- TPTE | c.1098G>T p.L366= (on ENST00000618007 / NM_199261.4; = p.L348= on NM_199259.4) | Silent (SNP) | VAF 16/374 reads (4%) | called by muse, mutect2
- TRIM48 | c.186C>A p.I62= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs1565077551, COSV70161798; called by muse, mutect2, varscan2
- TRPM4 | c.1815C>T p.D605= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV53264035; called by muse, mutect2, varscan2
- TRPS1 | c.936A>T p.S312= (on ENST00000220888 / NM_001330599.2; = p.S325= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/180 reads (36%) | catalogued as COSV55244214; called by muse, mutect2, varscan2
- UBN1 | c.2241G>A p.G747= | Silent (SNP) | VAF 43/176 reads (24%) | catalogued as COSV52168808; called by muse, mutect2, varscan2
- UTP3 | c.1374G>A p.E458= | Silent (SNP) | VAF 88/249 reads (35%) | catalogued as rs1281534297, COSV54661216; called by muse, mutect2, varscan2
- WASHC5 | c.2238G>T p.A746= | Silent (SNP) | VAF 80/218 reads (37%) | catalogued as COSV59197034; called by muse, mutect2, varscan2
- XKR4 | c.1470A>T p.P490= | Silent (SNP) | VAF 47/76 reads (62%) | catalogued as COSV59319680; called by muse, mutect2, varscan2
- XYLT1 | c.2100C>T p.I700= | Silent (SNP) | VAF 70/320 reads (22%) | catalogued as COSV54486257; called by muse, varscan2
- XYLT1 | c.1995G>T p.T665= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV54486273, COSV99763739; called by muse, mutect2, varscan2
- ZNF35 | c.858C>A p.A286= | Silent (SNP) | VAF 47/83 reads (57%) | called by muse, mutect2, varscan2
- ZPBP2 | c.981A>T p.P327= (on ENST00000348931 / NM_199321.3; = p.P305= on NM_198844.3) | Silent (SNP) | VAF 53/240 reads (22%) | catalogued as COSV62375340; called by muse, mutect2, varscan2
- ZXDA | c.1491G>A p.L497= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as COSV62388154; called by muse, mutect2, varscan2
- AGAP7P | n.1180dup | RNA (INS) | VAF 12/69 reads (17%) | catalogued as rs782113833; called by mutect2, pindel, varscan2
- C14orf177 | n.550C>T | RNA (SNP) | VAF 56/161 reads (35%) | catalogued as COSV57900294, COSV57900464; called by muse, varscan2
- C14orf177 | n.591C>A | RNA (SNP) | VAF 20/146 reads (14%) | catalogued as COSV57901053; called by muse, varscan2
- GRM8 | c.727+48378G>T | Intron (SNP) | VAF 25/134 reads (19%) | catalogued as rs1338681847, COSV58832082; called by muse, mutect2, varscan2
- HMGB1P1 | n.608A>T | RNA (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- KIF16B | c.3498+2799G>T | Intron (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- LRRC23 | c.*78A>G | 3'UTR (SNP) | VAF 70/206 reads (34%) | catalogued as rs782424785; called by muse, mutect2
- MIR1297 | n.21C>G | RNA (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- MIR517C | n.73G>T | RNA (SNP) | VAF 50/201 reads (25%) | called by muse, mutect2, varscan2
- MYL3 | chr3:46831918 C>A | 3'Flank (SNP) | VAF 51/85 reads (60%) | catalogued as COSV70133811; called by muse, mutect2, varscan2
